Gene-level copy-number profile of tumor specimen TCGA-33-4582-01A from TCGA case TCGA-33-4582, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 55.9 years (20,402 days).
Specimen TCGA-33-4582-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3dda2e58-5023-4872-b5fe-2ab588ebafbf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-33-4582-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a0871508-5e3f-41c1-acc4-bd7bf3df5c7c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 69; copy number 1: 4,532; copy number 2: 23,605; copy number 3: 17,780; copy number 4: 9,479; copy number 5: 2,698; copy number 6: 1,285; copy number 7: 282; copy number 8: 34; copy number 9: 48.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-33-4582-01A-01D-1439-01): tumor purity 0.54, ploidy 2.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:30,831,544–33,045,445, 25 genes: TEX15, AC090281.1, AC008066.1, PURG, WRN, SUMO2P16, AC009563.1, KCTD9P6, AC068672.2, AC068672.3, AC068672.1, AC090816.1, RNA5SP261, NRG1, AC068931.1, NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3, AC083977.1, RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,347 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–2,701,812, 43 genes, copy number 5: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN, MYT1L, AC093390.2, AC093390.1, MYT1L-AS1, AC018685.2, AC018685.3.
- chr2:2,729,908–2,730,957, 1 gene, copy number 5: AC018685.1.
- chr2:63,588,609–70,820,599, 153 genes, copy number 5–6 (broad region; genes not listed).
- chr2:148,260,574–148,260,708, 1 gene, copy number 5: AC019070.1.
- chr2:153,208,086–189,670,831, 507 genes, copy number 5–6 (broad region; genes not listed).
- chr3:97,759,523–132,285,410, 628 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr3:160,755,602–198,222,513, 658 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr4:55,215,624–56,033,361, 23 genes, copy number 6: RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135.
- chr6:9,596,110–23,031,780, 193 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr6:28,837,869–29,331,061, 33 genes, copy number 8: AL662890.1, LINC01623, RPL13P, ZNF90P2, HCG14, TRIM27, RNU6-930P, LINC01556, KRT18P1, RN7SL471P, HCG15, AL662791.1, ZNF311, OR2AD1P, AL662791.2, OR2W1, OR2P1P, SAR1AP1, OR2B3, OR2J1, OR2J3, AL645937.2, AL645937.1, AL645937.4, OR2J2, OR2J4P, AL645937.3, AL672167.1, OR2G1P, OR2U1P, OR2U2P, OR14J1, DDX6P1.
- chr6:29,373,423–29,375,291, 1 gene, copy number 8: OR12D3.
- chr6:60,719,222–67,546,754, 46 genes, copy number 5–6: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P.
- chr8:39,106,990–52,745,843, 202 genes, copy number 5 (broad region; genes not listed).
- chr11:39,261,107–42,253,721, 18 genes, copy number 6: RNU6-99P, AC021749.1, AC021820.1, AC080100.1, LRRC4C, Y_RNA, AC090720.1, RNU6-365P, AC090138.1, LINC02741, AC021006.1, AC021006.2, LINC01499, AC023442.1, AC023442.3, AC023442.2, LINC02745, LINC02740.
- chr11:48,985,868–50,422,316, 50 genes, copy number 5: TRIM53CP, AC027369.1, TRIM49B, AC084851.4, TRIM64C, AC084851.3, AC084851.1, UBTFL7, AC084851.2, AC118273.1, AC118273.2, TRIM77BP, UBTFL9, FOLH1, AC118942.1, TYRL, CBX3P8, AC135977.1, AC136759.1, AC130364.1, AC130364.2, TRIM51FP, AP006587.5, AP006587.6, AP006587.4, AP006587.3, TRIM51DP, AP006587.1, AP006587.2, OR4A1P, OR4A49P, OR4A18P, OR4A19P, OR4R3P, OR4C13, OR4C12, OR4C48P, OR4C45, OR4C49P, GTF2IP11, AC109635.3, AC109635.6, AC109635.5, PHKG1P3, AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1.
- chr11:65,444,458–77,994,671, 499 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:86,955,616–106,311,791, 331 genes, copy number 5 (broad region; genes not listed).
- chr11:114,059,711–116,823,304, 48 genes, copy number 5 (within-gene range 4–5): ZBTB16, AP002755.1, AP002518.2, NNMT, AP002518.1, C11orf71, RBM7, AP002373.1, REXO2, AP002373.2, NXPE2P1, AC020549.3, NXPE1, AC020549.1, NXPE4, AC020549.2, NXPE2, AP003179.1, CADM1, AP000465.1, AP000462.3, AP000462.1, AP000462.2, AP003174.2, AP003174.3, RPL12P46, AP003174.1, AP000997.1, AP000997.2, AP000997.3, AP000997.4, LINC02698, AP002991.1, AP002991.2, LINC00900, LINC02703, AP000797.2, AP000797.1, LINC02151, AP000770.1, LINC02702, BUD13, AP006216.1, ZPR1, APOA5, AP006216.2, AP006216.3, APOA4.
- chr11:133,297,189–134,412,242, 23 genes, copy number 6 (within-gene range 4–6): AP003972.1, OPCML-IT1, AP004606.1, LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1, GLB1L2, B3GAT1.
- chr12:63,844,700–64,162,217, 1 gene, copy number 6 (within-gene range 4–6): SRGAP1.
- chr12:63,887,379–73,679,296, 191 genes, copy number 6–9 (broad region; genes not listed).
- chr14:46,839,629–47,675,605, 1 gene, copy number 9 (within-gene range 3–9): MDGA2.
- chr14:47,200,575–48,046,216, 6 genes, copy number 9: RPL13AP2, RPS15AP3, MIR548Y, LINC00648, AL121576.1, AL359212.1.
- chr15:45,511,136–46,661,103, 17 genes, copy number 5 (within-gene range 4–5): HMGN2P46, SNORA41B, AC090527.1, DPPA5P2, AC090527.3, BLOC1S6, AC090527.2, Y_RNA, SQOR, AC068722.2, AC068722.1, AC068714.1, AC091074.3, MTND5P40, AC091074.1, AC091074.2, AC012405.1.
- chr17:68,511,780–72,058,073, 44 genes, copy number 5 (within-gene range 4–5): PRKAR1A, FAM20A, AC079210.1, LINC01482, AC011591.2, AC011591.1, ABCA8, ABCA9-AS1, ABCA9, ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804, AC005495.1, ABCA5, SNRPGP4, AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152.
- chr18:60,294,136–65,890,337, 69 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr19:31,797,666–32,244,083, 6 genes, copy number 5 (within-gene range 3–5): LINC01837, LINC01533, LINC01782, AC011518.1, AC074139.1, RNA5SP472.
- chr19:56,595,313–56,799,602, 1 gene, copy number 5 (within-gene range 4–5): ZIM2-AS1.
- chr19:56,661,980–58,605,223, 142 genes, copy number 5 (broad region; genes not listed).
- chr22:20,338,805–24,927,578, 330 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr22:37,550,026–38,998,209, 81 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,103. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
